Surgical pathology report (de-identified scan), TCGA case TCGA-5C-A9VH, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Cureline, specimen TCGA-5C-A9VH-01A (Primary Tumor).

ICD-O-3

Carcinoma, hepatocellular NOS 8170/3

Site: Liver C22.0

9/21/27/14

Case #

Patient: **Age (years):** **Gender:** M

Clinical diagnosis: Primary liver cancer

Date of procurement:

Sample: histology #

Gross description: Fifth and sixth segments of the liver and gall bladder single block 16x9x8 cm . Gall bladder wall is 0,2 cm, mucosa is pale brown color.Liver parenchyma shows nodular lobular mass 6,5x4cm . Gall bladder shows no signs of infiltrations .

Microscopic description: Nodular mass shows signs of hepatocellular cancer with moderate degree of differentiation and adenoid-trabecular structure with fibrotic tissue.

Lymphatic nodes and adjacent tissues show no signs of tumor growth.

Final diagnosis: Hepatocellular carcinoma.

Confidential

Source: NCI Genomic Data Commons file 046ff922-cdf5-4aa2-b441-d13298a40ad9 (TCGA-5C-A9VH.938BCE76-BF7D-4470-A409-805FD012D05D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).